Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PZ-01A (Primary Tumor).

[page 1 of 3]
HIP/ A Discrepancy		☒

Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to: INPATIENT

Clinical Diagnosis & History:
Papillary thyroid cancer.

Specimens Submitted:
1: Left paratracheal lymph node (fs)
2: Left lobe of thyroid and isthmus

DIAGNOSIS:

1. Left paratracheal lymph node (fs):
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 1

2. Left lobe of thyroid and isthmus:
Tumor Type: Papillary carcinoma, classical type

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Left lobe

Tumor Size:
Greatest diameter is 1.7 cm.

Tumor Encapsulation:
Partially surrounded

Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Invades: extrathyroidal adipose tissue
Focal

Surgical Margins:
Free of tumor

Tumor Multicentricity:

1CD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

lw
8/31/11

[page 2 of 3]
Not identified

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Not identified

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***
M.D.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

M.D.

1. The specimen is received fresh and is labeled "left para-tracheal lymph node". It consists of one piece of tan yellow soft tissue, measuring 0.5 x 0.5 x 0.4 cm. One lymph node is identified, measuring 0.3 cm in greatest dimension. Lymph node is entirely submitted for frozen section.

Summary of sections:
FSC- frozen section control

M.D.

2). The specimen is received fresh and is labeled "left lobe of thyroid and isthmus". It consists of a previously incised thyroid lobe measuring 4.5 x 2.5 x 1.5 cm and weighing 12 g. There is a 2 x 1 x 0.6 cm portion of skeletal muscle attached to the anterior aspect. The lobe is inked black posterior and blue anterior. Serial sectioning reveals 1.7 x 1.6 x 1.2 cm partially encapsulated hard tan nodule with gritty cut surface in the mid to upper lobe. The specimen is entirely submitted to include TPS.

Summary of sections:
N - nodule
RS - remaining sections

Summary of Sections:

Part 1: Left paratracheal lymph node (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left lobe of thyroid and isthmus

Block	Sect. Site	PCs
4	N	4
4	RS	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 3 of 3]
-
1. Frozen section diagnosis: Left paratracheal lymph node (fs): Benign
Permanent diagnosis:

Source: NCI Genomic Data Commons file 7a056b27-4291-44db-922a-85df7a12dd73 (TCGA-DJ-A2PZ.EDBA3217-6ED8-47CC-87F0-B18E41F29217.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).